Somatic mutation profile of tumor specimen TCGA-HE-A5NL-01A (aliquot TCGA-HE-A5NL-01A-11D-A26P-10) from TCGA case TCGA-HE-A5NL, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-HE-A5NL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07ea1b18-a1b2-4afe-9f51-472246574667.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HE-A5NL-10A (Blood Derived Normal), aliquot TCGA-HE-A5NL-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f3a8dea-1bcc-4cfd-884c-ab565772513c

The open-access MAF lists 87 somatic variants for this specimen: 59 protein-altering or splice-affecting, 22 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 22, Frame Shift Del 7, Frame Shift Ins 3, 3'UTR 3, Intron 2, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.3160G>A p.G1054R | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV55935647; called by muse, mutect2, varscan2
- ACBD5 | c.148A>C p.K50Q (on ENST00000375888 / NM_001352568.1; = p.K52Q on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101022458; called by muse, mutect2, varscan2
- ARHGAP24 | c.1757G>A p.G586E (on ENST00000395184 / NM_001025616.3; = p.G493E on NM_031305.3) | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV51989251; called by muse, mutect2, varscan2
- ARHGEF3 | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56326839; called by muse, mutect2, varscan2
- CADM3 | c.1183G>T p.E395* (on ENST00000368125 / NM_001127173.3; = p.E429* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 24/226 reads (11%) | catalogued as COSV63672093, COSV63672930; called by muse, mutect2, varscan2
- CASP8AP2 | c.4511G>T p.S1504I | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52747151; called by muse, mutect2, varscan2
- ELP3 | c.1592G>C p.R531T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV56459298; called by muse, mutect2, varscan2
- EPHX1 | c.970T>C p.Y324H | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55301020; called by muse, mutect2, varscan2
- EXOSC8 | c.782A>G p.E261G | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV53509300; called by muse, mutect2, varscan2
- FAT2 | c.8817C>A p.N2939K | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55812521, COSV55820191; called by muse, mutect2, varscan2
- FBXO30 | c.914G>A p.G305D | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52790258; called by muse, mutect2, varscan2
- FN1 | c.2103C>A p.S701R | Missense Mutation (SNP) | VAF 110/462 reads (24%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.93); catalogued as COSV60553552; called by muse, mutect2, varscan2
- GAS2 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV53405523, COSV53407728; called by muse, mutect2, varscan2
- HAND2 | c.124T>A p.Y42N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV64018209; called by muse, mutect2
- KBTBD3 | c.382T>A p.L128M | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV73241431; called by muse, mutect2, varscan2
- LGALS2 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV50756545; called by muse, mutect2
- LRRD1 | c.76T>A p.S26T | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.398); catalogued as COSV58469435; called by muse, mutect2, varscan2
- LYST | c.10024C>T p.R3342W | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67703516; called by muse, mutect2, varscan2
- MEGF11 | c.3010C>T p.H1004Y | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56551208; called by muse, mutect2, varscan2
- MEIOC | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV63439432, COSV63440192; called by muse, mutect2
- MEPCE | c.1835T>A p.I612N | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV52769224; called by muse, mutect2, varscan2
- MROH9 | c.1402C>G p.L468V | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV63011515; called by muse, mutect2, varscan2
- NAV2 | c.465T>A p.N155K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV62323241; called by muse, mutect2, varscan2
- NBPF15 | c.1800G>C p.E600D | Missense Mutation (SNP) | VAF 101/492 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs587634015, COSV68837437; called by muse, mutect2, varscan2
- NCOA1 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as rs896537625, COSV56044620; called by muse, mutect2
- NTM | c.758T>C p.F253S | Missense Mutation (SNP) | VAF 84/278 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100868539, COSV66180383; called by muse, mutect2, varscan2
- NWD2 | c.3770T>G p.F1257C | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58751795; called by muse, mutect2
- PAMR1 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 16/263 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53512602; called by muse, mutect2
- PDCD6IP | c.131A>C p.E44A | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs1428950487, COSV56243318; called by muse, mutect2, varscan2
- PDE2A | c.1878G>A p.M626I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV57807266; called by muse, mutect2, varscan2
- PNPLA3 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV53378382, COSV53379813; called by muse, mutect2, varscan2
- PRAMEF12 | c.1117A>T p.S373C | Missense Mutation (SNP) | VAF 198/685 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1406375412, COSV63215388; called by muse, mutect2, varscan2
- PSG11 | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV60454478, COSV60455306; called by muse, mutect2, varscan2
- RNF152 | c.328C>G p.R110G | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs764716205, COSV104397545, COSV57185583; called by muse, mutect2, varscan2
- SLC43A3 | c.903C>G p.N301K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV61450458; called by muse, mutect2, varscan2
- SPEN | c.5176G>A p.D1726N | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as rs1210776894, COSV65362297; called by muse, mutect2
- SPON2 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV52055129; called by muse, mutect2, varscan2
- TCHP | c.345A>T p.R115S | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV57165587; called by muse, mutect2, varscan2
- TIMM9 | c.29A>G p.Q10R | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53621652; called by muse, mutect2, varscan2
- TLN2 | c.6638T>A p.V2213E | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV60889993; called by muse, mutect2, varscan2
- TLR7 | c.3054C>A p.N1018K | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV66124365; called by muse, mutect2, varscan2
- TP53TG5 | c.203G>T p.R68M | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65577493; called by muse, mutect2, varscan2
- VWA8 | c.2968T>C p.F990L | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV55691753, COSV55697194; called by muse, mutect2, varscan2
- WDR72 | c.3206T>C p.V1069A | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV64742410; called by muse, mutect2, varscan2
- WDR81 | c.1925C>G p.P642R | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.444); catalogued as COSV58483077; called by muse, mutect2, varscan2
- ZACN | c.393G>T p.R131S | Missense Mutation (SNP) | VAF 108/274 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV58036192; called by muse, mutect2, varscan2
- ZNF337 | c.1699T>A p.S567T | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53321491; called by muse, mutect2, varscan2
- ZNF415 | c.538A>T p.I180L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV54701494; called by muse, mutect2
- ZNF79 | c.760T>C p.C254R | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV61070975; called by muse, mutect2
- ATP13A1 | c.2312_2318dup p.Q773Hfs*18 | Frame Shift Ins (INS) | VAF 56/221 reads (25%) | called by mutect2, varscan2
- CENPK | c.535_542del p.T179Rfs*11 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- GAD1 | c.1144del p.M382Cfs*12 | Frame Shift Del (DEL) | VAF 43/138 reads (31%) | called by mutect2, pindel, varscan2
- NUP88 | c.758dup p.F254Ifs*8 | Frame Shift Ins (INS) | VAF 51/247 reads (21%) | called by mutect2, pindel, varscan2
- RGMB | c.444_445del p.E149Tfs*28 (on ENST00000513185 / NM_001366508.1; = p.E190Tfs*28 on NM_001012761.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 52/192 reads (27%) | called by mutect2, pindel, varscan2
- SEL1L3 | c.1518dup p.H507Tfs*22 | Frame Shift Ins (INS) | VAF 42/183 reads (23%) | called by mutect2, pindel, varscan2
- SLC25A40 | c.901del p.S301Qfs*3 | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | called by mutect2, pindel, varscan2
- TRIM55 | c.1098del p.P367Qfs*44 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- TTL | c.709del p.T237Pfs*4 | Frame Shift Del (DEL) | VAF 28/124 reads (23%) | called by mutect2, pindel, varscan2
- TUT1 | c.1821_1834del p.I609Cfs*58 | Frame Shift Del (DEL) | VAF 33/124 reads (27%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.2457A>G p.E819= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV51847568; called by muse, mutect2, varscan2
- ATRNL1 | c.2970G>A p.E990= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as COSV58089330; called by muse, mutect2, varscan2
- C2orf81 | c.429C>T p.P143= | Silent (SNP) | VAF 50/156 reads (32%) | catalogued as COSV51763690; called by muse, mutect2, varscan2
- FAM47A | c.1560G>A p.E520= | Silent (SNP) | VAF 48/72 reads (67%) | catalogued as COSV60496953, COSV60498393; called by muse, mutect2, varscan2
- FAT4 | c.1542T>C p.I514= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as COSV67887270; called by muse, mutect2, varscan2
- G3BP2 | c.1233T>A p.A411= | Silent (SNP) | VAF 59/215 reads (27%) | catalogued as COSV62976417; called by muse, mutect2, varscan2
- IL21R | c.996G>T p.T332= | Silent (SNP) | VAF 60/239 reads (25%) | catalogued as COSV61970567, COSV61970979; called by muse, mutect2, varscan2
- KIF4B | c.2082G>A p.Q694= | Silent (SNP) | VAF 73/300 reads (24%) | catalogued as COSV70529427; called by muse, mutect2, varscan2
- KLB | c.927G>T p.R309= | Silent (SNP) | VAF 110/342 reads (32%) | catalogued as COSV57301953; called by muse, mutect2, varscan2
- KLHDC4 | c.663G>A p.L221= | Silent (SNP) | VAF 127/242 reads (52%) | catalogued as COSV54508261; called by muse, mutect2, varscan2
- LRPPRC | c.699A>T p.A233= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV53238559; called by muse, mutect2, varscan2
- MED12L | c.1005C>T p.G335= | Silent (SNP) | VAF 50/102 reads (49%) | catalogued as rs770375092, COSV56379857; called by muse, mutect2, varscan2
- MUC5B | c.5982C>T p.R1994= | Silent (SNP) | VAF 351/1171 reads (30%) | catalogued as COSV71592130; called by muse, mutect2, varscan2
- MYO7A | c.2670G>A p.K890= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV68684815; called by muse, mutect2, varscan2
- PCK1 | c.1815C>A p.P605= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as COSV60128235; called by muse, mutect2, varscan2
- PLEKHD1 | c.1161G>A p.E387= | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as COSV59447033; called by muse, mutect2, varscan2
- POLR2C | c.543G>A p.G181= | Silent (SNP) | VAF 165/309 reads (53%) | catalogued as COSV54672720; called by muse, mutect2, varscan2
- PRKAR1A | c.1047G>A p.K349= | Silent (SNP) | VAF 10/348 reads (3%) | catalogued as COSV56836740; called by muse, mutect2
- SEL1L2 | c.714C>A p.A238= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV53152558; called by muse, mutect2, varscan2
- SLC35B1 | c.750A>T p.T250= (on ENST00000649906; = p.T213= on NM_005827.4) | Silent (SNP) | VAF 95/404 reads (24%) | catalogued as COSV53603095; called by muse, mutect2, varscan2
- TECPR1 | c.3351G>A p.E1117= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV58362980; called by muse, mutect2, varscan2
- ZGPAT | c.1281T>A p.P427= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV56649709; called by muse, mutect2, varscan2
- ATXN7L3B | c.*1236C>G | 3'UTR (SNP) | VAF 53/121 reads (44%) | catalogued as COSV101576279, COSV101576314; called by muse, mutect2, varscan2
- BRD1 | c.2360-66C>G | Intron (SNP) | VAF 38/147 reads (26%) | called by muse, mutect2, varscan2
- KMT5B | c.1174+1016T>C | Intron (SNP) | VAF 77/264 reads (29%) | catalogued as COSV100429846; called by muse, mutect2, varscan2
- NPY2R | c.*981C>T | 3'UTR (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100279399; called by muse, mutect2, varscan2
- PURA | c.*2780T>A | 3'UTR (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- ZCCHC18 | chrX:104115622 del AA | 3'Flank (DEL) | VAF 15/25 reads (60%) | called by mutect2, pindel, varscan2
